Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JU-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site breast, NOS C50.9 3/1/11

page 1 / 1

Department of Cancer Pathology

Examination: Histopathological examination

Examination No.:

Patient: PESEL: Age: Gender: F

Material: Multiple organ resection – left breast

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast – lesion in the upper outer quadrant.

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 20 x 13 x 2 cm removed without axillary tissues. Skin flap

20 x 9.5 cm in size. Tumour sized 1.7 x 1.8 x 1.5 cm found on the boundary of outer quadrants, placed 2 cm from the lower edge, 0.2 cm from the base and 1.0 cm from the skin. Cysts of 0.1 – 0.5 cm in the cross-section.

Microscopic description:

Carcinoma ductale invasivum NHG1 (2+2+1 /1 mitosis /10 HPF, vision area diameter 0.57 mm)

Additionally, focuses of carcinoma ductale in situ: cribrate type with medium nuclear atopia, no necrosis, found in the glandular tissue (30% of the tumour cross-section).

Glandular tissue showing lesions of the type: mastopathia fibrosa et cystica, adenosis sclerosans, fiat epithelial atypia (FEA). fibrocystic changes, sclerosing adenosis

Histopathological diagnosis:

(including test No. G-I5785/10):

Carcinoma ductale invasivum et in situ mammae sinistrae.

(NHG 1, pT1c, pN0/sn/).

Invasive and in situ ductal carcinoma of the left breast

Compliance validated by:

Dual (Synch) Primary Noted		
Case is Circumstantial		
Revised Final		

Source: NCI Genomic Data Commons file 81588427-8e7e-49f0-b28b-97b09967cf03 (TCGA-D8-A1JU.B5074D1A-C617-414F-B349-6096F59E122D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).